Somatic mutation profile of tumor specimen C3N-01898-04 (aliquot CPT0162380035) from CPTAC case C3N-01898, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 49.1 years (17,926 days).
Specimen C3N-01898-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17e8c72c-9024-4921-badc-a7dadb9a50ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01898-31 (Blood Derived Normal), aliquot CPT0162430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd8638a3-8c99-487f-b75f-3a3e0ee845ea

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 23/462 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 26/596 reads (4%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- CSMD3 | c.2530C>T p.R844W (on ENST00000297405 / NM_001363185.1; = p.R740W on NM_052900.3) | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777713609, COSV52105465; called by muse, mutect2
- MATN4 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | PolyPhen probably damaging (0.994); catalogued as COSV59212745; called by muse, mutect2
- PDYN | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 24/501 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs1393045758, COSV99453450; called by muse, mutect2
- RIMBP2 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 32/744 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs772503598, COSV99900069, COSV99900431; called by muse, mutect2
- RTL1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 17/354 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as rs1216914274; called by muse, mutect2
- TERT | c.2516C>T p.T839M | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748503447; ClinVar: uncertain significance; called by muse, mutect2
- WDR45 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 28/437 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs782798113; called by muse, mutect2
- COL6A5 | c.3238G>A p.G1080R | Missense Mutation (SNP) | VAF 24/598 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM47C | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- SCRIB | c.1288C>A p.Q430K | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.209); called by muse, mutect2
- TBX22 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 22/461 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- TKTL1 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.403); called by muse, mutect2
- ATRX | c.3774G>T p.V1258= | Silent (SNP) | VAF 30/543 reads (6%) | called by muse, mutect2
- FRMPD4 | c.3378C>T p.A1126= | Silent (SNP) | VAF 18/318 reads (6%) | catalogued as rs755813000, COSV66213810; called by muse, mutect2
- IGHV1-46 | c.336G>T p.V112= | Silent (SNP) | VAF 21/590 reads (4%) | catalogued as rs539648580; called by muse, mutect2
- MAMLD1 | c.1314C>T p.T438= | Silent (SNP) | VAF 34/733 reads (5%) | catalogued as rs782756914; called by muse, mutect2
- NLRC5 | c.2742G>T p.G914= | Silent (SNP) | VAF 38/700 reads (5%) | called by muse, mutect2
- RAB40B | c.393G>A p.A131= | Silent (SNP) | VAF 14/232 reads (6%) | catalogued as rs769582459, COSV53916677; called by muse, mutect2
- TRIM64 | c.240C>T p.T80= | Silent (SNP) | VAF 28/899 reads (3%) | called by muse, mutect2
- KRT8P11 | n.933C>T | RNA (SNP) | VAF 24/524 reads (5%) | called by muse, mutect2
- SMARCA4 | c.1593+165G>A | Intron (SNP) | VAF 39/766 reads (5%) | catalogued as rs1437073300; called by muse, mutect2
